Somatic mutation profile of tumor specimen TCGA-ZC-AAA7-01A (aliquot TCGA-ZC-AAA7-01A-11D-A428-09) from TCGA case TCGA-ZC-AAA7, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 63.7 years (23,265 days).
Specimen TCGA-ZC-AAA7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d6a2118-6a99-4fc8-9f7e-a2e13f0ee62d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZC-AAA7-10A (Blood Derived Normal), aliquot TCGA-ZC-AAA7-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be10a87e-de09-429a-8e4e-0229ae2bca60

The open-access MAF lists 81 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 16, Frame Shift Del 4, Splice Site 2, Nonsense Mutation 2, RNA 2, Frame Shift Ins 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.2084G>C p.R695T (on ENST00000506720 / NM_001322402.2; = p.R627T on NM_015236.6) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV72231147; called by muse, mutect2
- ADGRV1 | c.12487G>T p.G4163W | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101316547; called by muse, mutect2
- C1orf127 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as rs370186380; called by muse, mutect2, varscan2
- CACNA1I | c.5498C>T p.S1833F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV60819023; called by muse, mutect2, varscan2
- CLASP2 | c.3707G>A p.R1236H (on ENST00000359576; = p.R1235H on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746484508, COSV56295564; called by muse, mutect2, varscan2
- CYB561 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1162440319; called by muse, mutect2, varscan2
- CYLD | c.2018C>T p.S673L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV61098408; called by muse, mutect2, varscan2
- DNAH3 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV54548360; called by muse, mutect2, varscan2
- ECM1 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV60871868; called by muse, mutect2, varscan2
- ERICH5 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as rs750195428; called by muse, mutect2, varscan2
- FBN3 | c.2555-1G>C p.X852_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | catalogued as rs746823264; called by mutect2, varscan2
- GAPVD1 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.971); catalogued as rs1480955826; called by muse, mutect2, varscan2
- GTF3C1 | c.315G>C p.E105D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV99851490; called by muse, mutect2, varscan2
- H2AW | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.799); catalogued as rs1411867732; called by muse, mutect2, varscan2
- H2BC3 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.991); catalogued as rs1561922655, COSV63551480; called by muse, mutect2, varscan2
- KIR2DL1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); catalogued as rs770336992; called by muse, mutect2, varscan2
- LSMEM1 | c.256G>T p.V86F | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as COSV100456187; called by muse, mutect2, varscan2
- MED28 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as rs1184531320; called by muse, mutect2, varscan2
- MYG1 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs142952424; called by muse, mutect2, varscan2
- MYH1 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs769065198, COSV56853251; called by muse, mutect2, varscan2
- NFRKB | c.697C>A p.L233M (on ENST00000446488 / NM_001143835.2; = p.L258M on NM_006165.3) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100452032; called by muse, mutect2
- NKAP | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV65057085; called by muse, mutect2, varscan2
- NLRP12 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60746255; called by muse, mutect2, varscan2
- PAX7 | c.1459C>T p.L487F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.501); catalogued as rs927869403; called by muse, mutect2, varscan2
- PIAS4 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99518673; called by muse, mutect2, varscan2
- PLCB3 | c.2507C>T p.P836L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs142407686; called by muse, mutect2, varscan2
- PTPRD | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs772278559, COSV61925462; called by muse, mutect2, varscan2
- SLC2A14 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs770629394, COSV61586130; called by muse, mutect2, varscan2
- STARD13 | c.2635C>G p.R879G (on ENST00000336934 / NM_001243476.3; = p.R761G on NM_052851.3) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.201); catalogued as rs142383363; called by muse, mutect2, varscan2
- USP30 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs760327509, COSV57448404; called by muse, mutect2, varscan2
- ZNF420 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs187475418; called by muse, mutect2, varscan2
- ABI3BP | c.1243A>C p.T415P | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- AFDN | c.2827G>A p.D943N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BMP2 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CHL1 | c.3205+1G>C p.X1069_splice (on ENST00000397491 / NM_001253387.1; = p.X1085_splice on NM_006614.4) | Splice Site (SNP) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- COL4A1 | c.2596C>A p.Q866K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- DAPK1 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCLRE1A | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH1 | c.12451G>C p.E4151Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FZR1 | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by mutect2, varscan2
- GPR180 | c.607del p.H203Tfs*2 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- HECTD4 | c.2347G>A p.G783S | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- IRF1 | c.393dup p.K132* | Frame Shift Ins (INS) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- KLC1 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- MMP13 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PDCL2 | c.502A>T p.K168* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- PRAMEF2 | c.177del p.W59Cfs*11 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | called by mutect2, pindel, varscan2
- RNF169 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- RREB1 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- SFPQ | c.959A>G p.Y320C | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SGK1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- SIPA1L2 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLC45A4 | c.2216G>A p.R739K (on ENST00000517878 / NM_001286646.2; = p.R688K on NM_001080431.2) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYNE2 | c.18887del p.N6296Ifs*15 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- TEX33 | c.450T>A p.F150L (on ENST00000381821 / NM_001163857.2; = p.F65L on NM_178552.4) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNFAIP3 | c.19_22del p.P7Rfs*5 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- TTN | c.37661C>G p.T12554S (on ENST00000591111; = p.T5130S on NM_003319.4) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | PolyPhen benign (0.014); called by muse, mutect2
- TXK | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- USP32 | c.3297C>G p.S1099R | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- WDR62 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ZNF25 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- BANK1 | c.219G>A p.L73= | Silent (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
- CCDC87 | c.1572G>A p.S524= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs753382789; called by muse, mutect2, varscan2
- CHRM2 | c.294T>C p.L98= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- CLIP1 | c.3756G>C p.L1252= (on ENST00000620786 / NM_001247997.1; = p.L1241= on NM_002956.2) | Silent (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- CUBN | c.7284C>T p.V2428= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- MYH7 | c.117G>T p.V39= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- MYO15A | c.4464C>T p.V1488= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52751190; called by mutect2, varscan2
- NAA16 | c.39C>T p.L13= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1437279785, COSV101038431; called by muse, mutect2
- NOMO1 | c.3609C>T p.D1203= | Silent (SNP) | VAF 29/197 reads (15%) | called by muse, mutect2, varscan2
- PCDHB7 | c.2214C>T p.S738= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV50758039, COSV50800092; called by muse, mutect2, varscan2
- PLCG2 | c.2622C>T p.F874= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- POLE2 | c.1155C>T p.I385= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as rs761047090; called by muse, mutect2, varscan2
- RNF213 | c.6438G>C p.L2146= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV60394218; called by muse, mutect2, varscan2
- SEC14L5 | c.1476C>G p.L492= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs770345985; called by muse, mutect2, varscan2
- USH2A | c.11455C>T p.L3819= | Silent (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- USP42 | c.1464C>T p.S488= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV60364229; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851281 T>A | 3'Flank (SNP) | VAF 15/23 reads (65%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1393G>A | RNA (SNP) | VAF 8/59 reads (14%) | catalogued as rs763231386; called by muse, mutect2, varscan2
- MSLNL | c.37+1309C>A | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- OSGIN1 | n.500G>T | RNA (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100652462; called by muse, varscan2
